Somatic mutation profile of tumor specimen TCGA-EE-A2MG-06A (aliquot TCGA-EE-A2MG-06A-11D-A197-08) from TCGA case TCGA-EE-A2MG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 27.9 years (10,198 days).
Specimen TCGA-EE-A2MG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e50953f8-95ff-4b9d-9a1b-99097d7cb024.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MG-10A (Blood Derived Normal), aliquot TCGA-EE-A2MG-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/461f7fb3-3462-4326-a858-267537017a4f

The open-access MAF lists 231 somatic variants for this specimen: 155 protein-altering or splice-affecting, 72 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 72, Nonsense Mutation 7, Intron 3, Splice Region 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56984819, COSV56985325; called by mutect2, varscan2
- STK19 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs267600971, COSV61712753; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 18/88 reads (20%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56856494; called by muse, mutect2, varscan2
- ABCD3 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100931466; called by mutect2, varscan2
- ABCD3 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100931467; called by muse, mutect2, varscan2
- ACSBG1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs779018573, COSV51906355, COSV99357242; called by mutect2, varscan2
- ACSM2B | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV61659664; called by muse, mutect2, varscan2
- ACTC1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51761104; called by muse, mutect2, varscan2
- ADAMTS6 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV66863872; called by mutect2, varscan2
- ADGRV1 | c.12481C>T p.L4161F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV67993781; called by muse, mutect2, varscan2
- ADORA3 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53986718; called by muse, mutect2, varscan2
- ANGPT1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.206); catalogued as COSV52454440; called by muse, mutect2, varscan2
- ANK2 | c.9512C>T p.S3171L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.369); catalogued as COSV52183960; called by mutect2, varscan2
- APLF | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58148186; called by muse, mutect2, varscan2
- APOB | c.8233C>T p.H2745Y | Missense Mutation (SNP) | VAF 79/556 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV51949504; called by muse, mutect2, varscan2
- ARMC4 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV59456008; called by muse, mutect2, varscan2
- ASB15 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV51928610; called by muse, mutect2, varscan2
- ATP11B | c.3437C>T p.P1146L | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV60032768; called by muse, mutect2, varscan2
- ATP13A5 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60874363; called by muse, mutect2, varscan2
- BRINP1 | c.1802C>T p.T601I | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV56311223; called by muse, mutect2, varscan2
- C1QTNF3 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.667); catalogued as COSV51469734; called by muse, mutect2, varscan2
- C1orf116 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100847965, COSV63944593; called by muse, mutect2, varscan2
- C7orf33 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV61023822; called by muse, mutect2, varscan2
- CACHD1 | c.2336T>C p.V779A | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.788); catalogued as COSV51559071; called by muse, mutect2, varscan2
- CACNA2D3 | c.3115A>C p.K1039Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV55574331; called by muse, mutect2, varscan2
- CADM2 | c.755G>A p.G252E (on ENST00000407528 / NM_001167674.2; = p.G254E on NM_153184.4) | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67357577; called by muse, varscan2
- CAMK4 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV56680781; called by muse, mutect2, varscan2
- CASC3 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV52869059; called by muse, mutect2, varscan2
- CCDC142 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV99282377; called by muse, mutect2, varscan2
- CCDC144A | c.2411A>G p.N804S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV60701323; called by muse, mutect2, varscan2
- CCDC146 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53553367; called by muse, mutect2, varscan2
- CCDC42 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs781125276, COSV53448814; called by mutect2, varscan2
- CCR6 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as rs139697820; called by muse, mutect2, varscan2
- CD33 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.267); catalogued as COSV99220782; called by muse, mutect2
- CGNL1 | c.2126A>G p.E709G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV55573975; called by muse, mutect2, varscan2
- CHD3 | c.5236T>G p.Y1746D (on ENST00000330494 / NM_001005273.3; = p.Y1712D on NM_005852.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57879479; called by muse, mutect2, varscan2
- CHD5 | c.1772G>A p.W591* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV52423295, COSV99313521; called by muse, varscan2
- CLVS2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866387612, COSV51568165; called by mutect2, varscan2
- CNKSR2 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV54264543; called by muse, mutect2, varscan2
- COL14A1 | c.5234G>A p.G1745E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV52852528; called by muse, mutect2, varscan2
- COL5A3 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53417867; called by muse, varscan2
- CYP7B1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59595742; called by muse, mutect2, varscan2
- DDB1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57105278; called by muse, mutect2, varscan2
- DDX60 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV67098778; called by muse, mutect2, varscan2
- DIDO1 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV99827146; called by muse, varscan2
- DISP3 | c.3671C>T p.T1224I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV53835964; called by muse, mutect2, varscan2
- DNAJC8 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV55282907; called by muse, mutect2, varscan2
- DRP2 | c.2261A>T p.Y754F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV65811605; called by muse, mutect2, varscan2
- EBF2 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs776859966, COSV68776429; called by muse, mutect2, varscan2
- ELAPOR2 | c.2729G>A p.G910E (on ENST00000450689 / NM_001142749.3; = p.G743E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51890997; called by muse, mutect2
- ENAM | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs745482726, COSV68536094; called by mutect2, varscan2
- EPHA7 | c.2112G>A p.G704= | Splice Region (SNP) | VAF 8/66 reads (12%) | catalogued as COSV65187000; called by muse, mutect2, varscan2
- FAM124B | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54739860; called by muse, mutect2, varscan2
- FAM3B | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as rs534909446, COSV63613157; called by mutect2, varscan2
- FAM83A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.596); catalogued as COSV52687472; called by muse, mutect2, varscan2
- FBXO24 | c.526C>T p.R176C (on ENST00000241071 / NM_033506.3; = p.R214C on NM_012172.5) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.928); catalogued as rs746919360, COSV53829016; called by mutect2, varscan2
- FGD5 | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.387); catalogued as COSV53250449; called by muse, mutect2, varscan2
- FGFR2 | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60657108; called by mutect2, varscan2
- FLNB | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745588918, COSV55892924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100421030; called by mutect2, varscan2
- FOSL2 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767171135, COSV53105459; called by mutect2, varscan2
- GCNT3 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68532460; called by muse, mutect2, varscan2
- GFRAL | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs757085738, COSV61234768; called by muse, mutect2, varscan2
- GRHL2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52548521; called by muse, mutect2
- GRM8 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as COSV58861097; called by muse, mutect2, varscan2
- HOXA4 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415696; called by mutect2, varscan2
- IFIT1B | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs779271234, COSV65663406; called by mutect2, varscan2
- IGFL2 | c.137A>G p.N46S (on ENST00000377693 / NM_001135113.2; = p.N57S on NM_001002915.2) | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs748954556, COSV66617370; called by muse, mutect2, varscan2
- IGSF10 | c.5999C>T p.S2000F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs550459840, COSV56393957; called by muse, mutect2, varscan2
- INPP5D | c.1279C>T p.L427F (on ENST00000445964 / NM_001017915.3; = p.L426F on NM_005541.5) | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV104422278, COSV64039460; called by muse, mutect2
- IPO4 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100269006, COSV100269240; called by muse, mutect2, varscan2
- ITGA9 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53250999; called by muse, mutect2
- KANK4 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV62988920; called by muse, mutect2, varscan2
- KBTBD8 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.548); catalogued as COSV55130997; called by muse, mutect2, varscan2
- KCNQ5 | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1344408352, COSV59678990; called by muse, mutect2, varscan2
- KDM7A | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV50095150; called by muse, mutect2, varscan2
- KIF4A | c.2338C>G p.Q780E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.24); catalogued as COSV63285178; called by muse, mutect2, varscan2
- KIR2DL1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99382642, COSV99383657; called by muse, mutect2, varscan2
- KRT34 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV67449725; called by muse, mutect2, varscan2
- LRRC4B | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV65349105; called by muse, mutect2, varscan2
- MAGI3 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56842998; called by muse, mutect2
- MAGI3 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV56843008; called by muse, mutect2, varscan2
- MAP1B | c.5356C>T p.P1786S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57104998; called by muse, mutect2
- MAP3K19 | c.2388G>A p.M796I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV59641623; called by muse, mutect2, varscan2
- MFNG | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV63690777; called by muse, mutect2, varscan2
- MGAT5B | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56935592; called by muse, mutect2, varscan2
- MMD2 | c.788C>T p.T263I (on ENST00000404774 / NM_001100600.2; = p.T239I on NM_198403.4) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV68661460; called by muse, mutect2, varscan2
- MOV10L1 | c.2543G>A p.G848E | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV53178048; called by muse, mutect2, varscan2
- MPP3 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV68199083; called by muse, mutect2, varscan2
- MUC16 | c.6046C>T p.H2016Y | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV67475009, COSV67488606; called by muse, mutect2, varscan2
- MUC17 | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV60300816; called by muse, mutect2, varscan2
- MXRA5 | c.7040C>T p.T2347I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54247561; called by muse, mutect2, varscan2
- NELL1 | c.1824G>A p.W608* | Nonsense Mutation (SNP) | VAF 13/137 reads (9%) | catalogued as COSV54315247, COSV54323175; called by muse, mutect2
- OASL | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV57480236; called by muse, mutect2, varscan2
- OPLAH | c.3763G>A p.D1255N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.229); catalogued as rs782277879, COSV66299840; called by muse, varscan2
- OR13C8 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58612259; called by muse, mutect2, varscan2
- OR2M3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs765663539, COSV71758955; called by muse, mutect2, varscan2
- OR4D1 | c.527A>C p.N176T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as COSV52125887; called by muse, mutect2, varscan2
- OR8K5 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as rs147577134, COSV57889485; called by muse, varscan2
- OSBP | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV55665242; called by mutect2, varscan2
- OSMR | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV57090721; called by muse, mutect2, varscan2
- PCDHA8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV65325085; called by muse, mutect2, varscan2
- PCDHB3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as COSV50620695; called by muse, mutect2, varscan2
- PDE10A | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV63093958; called by muse, mutect2, varscan2
- PDE8B | c.1573A>G p.K525E | Missense Mutation (SNP) | VAF 77/453 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV53743866; called by muse, mutect2, varscan2
- PHF14 | c.2582A>G p.K861R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV68857007; called by muse, mutect2
- PIGV | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs1320617918, COSV50292416; called by muse, mutect2, varscan2
- PIK3R1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV99154336; called by muse, mutect2, varscan2
- PKD1 | c.5909C>T p.A1970V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV51924292; called by mutect2, varscan2
- PKHD1L1 | c.5383G>A p.E1795K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV65746958; called by mutect2, varscan2
- PLEKHG4 | c.2992C>T p.R998C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199974367, COSV58574202; called by muse, mutect2, varscan2
- PSD4 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs1320306467, COSV55524914; called by muse, mutect2, varscan2
- PTPRH | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54749207, COSV54749379; called by muse, mutect2, varscan2
- RELB | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55512512; called by muse, mutect2, varscan2
- RGS21 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV101313999, COSV69883489; called by mutect2, varscan2
- RPRD2 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); catalogued as rs1256466926, COSV64822924; called by muse, mutect2, varscan2
- RPS7 | c.462A>G p.I154M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.292); catalogued as COSV59232977, COSV59233435; called by muse, mutect2, varscan2
- SDR16C5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV58126151; called by mutect2, varscan2
- SELENBP1 | c.710A>G p.E237G | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV64374087; called by muse, varscan2
- SERPINA4 | c.656G>A p.W219* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV54071382; called by muse, mutect2, varscan2
- SH3GL2 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as COSV66054462; called by muse, mutect2, varscan2
- SLC10A1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs770345573, COSV53683793; called by muse, mutect2, varscan2
- SLC25A13 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as COSV55709300; called by muse, mutect2, varscan2
- SLIT2 | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV56566803; called by muse, mutect2, varscan2
- SNTG1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); catalogued as COSV52467430; called by muse, mutect2, varscan2
- SORBS2 | c.857G>A p.G286E (on ENST00000284776 / NM_021069.5; = p.G379E on NM_003603.6) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV53012663; called by muse, mutect2, varscan2
- SPOCK3 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62730151; called by muse, mutect2, varscan2
- SRSF11 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs140006011, COSV63937685; called by muse, mutect2, varscan2
- STXBP4 | c.1208A>G p.K403R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64467039; called by muse, mutect2, varscan2
- STYK1 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV50014942; called by muse, mutect2, varscan2
- SV2B | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs776050433, COSV100370469, COSV57700676, COSV57701598; called by muse, mutect2, varscan2
- TAFA1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV72040638; called by muse, mutect2, varscan2
- TET3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV59882412; called by muse, mutect2, varscan2
- TLL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50265437; called by muse, mutect2, varscan2
- TRPC3 | c.1052G>A p.R351Q (on ENST00000379645 / NM_001366479.2; = p.R278Q on NM_003305.2) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as rs148910203; called by mutect2, varscan2
- TRPM6 | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs746442748, COSV62519124, COSV62520793; called by muse, mutect2, varscan2
- TTN | c.59542C>T p.H19848Y (on ENST00000591111; = p.H12424Y on NM_003319.4) | Missense Mutation (SNP) | VAF 38/233 reads (16%) | PolyPhen benign (0.003); catalogued as rs1412094100, COSV60294023; called by muse, mutect2, varscan2
- TTN | c.48680G>A p.R16227K (on ENST00000591111; = p.R8803K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | PolyPhen benign (0.013); catalogued as COSV60294054; called by muse, mutect2, varscan2
- UGT2B15 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs146368165; called by mutect2, varscan2
- VWA3B | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as rs1299336855, COSV68242088; called by muse, mutect2, varscan2
- XIRP2 | c.6790G>A p.D2264N (on ENST00000628543; = p.D2439N on NM_152381.6) | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs563915541, COSV54679859; called by muse, varscan2
- ZBBX | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1338202487, COSV56797664; called by muse, mutect2, varscan2
- ZBTB40 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65146243; called by muse, mutect2, varscan2
- ZNF225 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs776781872, COSV53472946; called by muse, mutect2, varscan2
- ZNF506 | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV71354646; called by muse, mutect2, varscan2
- ZNF521 | c.2087G>T p.C696F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64131059; called by muse, mutect2, varscan2
- ZNF578 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.649); catalogued as rs185671122, COSV69736189; called by mutect2, varscan2
- ZNF582 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV56733509; called by mutect2, varscan2
- ZNF638 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs777449446, COSV52495311; called by muse, mutect2
- ZNF721 | c.1363C>T p.H455Y (on ENST00000338977; = p.H467Y on NM_133474.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV59096345; called by mutect2, varscan2
- ZNF76 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1230810854, COSV57592597; called by muse, varscan2
- ZNF804A | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.03); catalogued as COSV56467694; called by muse, mutect2, varscan2
- PRAMEF19 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); called by muse, varscan2
- ACSF2 | c.1389C>T p.I463= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV51973518, COSV51973964; called by muse, mutect2, varscan2
- ADPRH | c.78C>T p.F26= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1428722850, COSV63694800; called by muse, mutect2, varscan2
- AK5 | c.795C>T p.D265= (on ENST00000354567 / NM_174858.3; = p.D239= on NM_012093.4) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs767151466, COSV60979977; called by mutect2, varscan2
- ALB | c.411C>T p.P137= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV55741789; called by muse, mutect2
- ALPI | c.1200G>A p.K400= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99786171; called by muse, mutect2, varscan2
- ARHGEF11 | c.2833C>T p.L945= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as rs1369278302, COSV59358039; called by muse, mutect2
- BAHD1 | c.2217C>T p.P739= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV60379409; called by muse, mutect2, varscan2
- C8B | c.1611C>T p.S537= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV64779290; called by muse, mutect2, varscan2
- CCR3 | c.387C>T p.I129= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs199716185, COSV62465585; called by muse, mutect2, varscan2
- CDC37 | c.150G>A p.L50= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV55769562; called by muse, mutect2, varscan2
- CERS2 | c.114T>C p.D38= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV54991194; called by muse, mutect2
- CLMP | c.249G>A p.V83= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV71650517; called by muse, mutect2, varscan2
- CNOT10 | c.1353G>A p.S451= | Silent (SNP) | VAF 34/226 reads (15%) | catalogued as rs147797250; called by muse, mutect2, varscan2
- CNTN4 | c.2289G>A p.R763= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV61879758; called by muse, mutect2, varscan2
- COL6A3 | c.2748G>T p.L916= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV55105586; called by mutect2, varscan2
- DENND2A | c.249G>A p.R83= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs760072663, COSV52057715; called by muse, varscan2
- DENND2C | c.1680C>T p.S560= (on ENST00000393274 / NM_001256404.2; = p.S503= on NM_198459.4) | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV67923722; called by muse, mutect2
- DGLUCY | c.606C>T p.I202= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV56369680; called by muse, mutect2, varscan2
- EPB41L1 | c.2166C>T p.S722= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs138806418; called by muse, mutect2, varscan2
- EPPK1 | c.888C>T p.G296= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV73262305; called by muse, mutect2, varscan2
- ERRFI1 | c.981G>A p.P327= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs766752153, COSV66310655; called by muse, mutect2, varscan2
- ETV1 | c.936C>T p.F312= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as rs765227604, COSV54137697; called by mutect2, varscan2
- ETV3L | c.417C>T p.S139= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV71901154; called by muse, mutect2
- FER1L6 | c.1908C>T p.F636= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1264254333, COSV67552377; called by mutect2, varscan2
- FRK | c.492C>T p.H164= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV73384195; called by muse, mutect2, varscan2
- GLYCTK | c.721C>T p.L241= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1284755036, COSV59794638; called by muse, mutect2, varscan2
- GRM8 | c.2391C>T p.F797= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV58802924; called by mutect2, varscan2
- HCK | c.456G>A p.K152= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52946452; called by muse, mutect2, varscan2
- HOXA4 | c.723C>T p.T241= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100415698; called by muse, mutect2, varscan2
- IPO4 | c.2037C>T p.A679= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1362384604, COSV100269003; called by mutect2, varscan2
- IQSEC1 | c.1290C>T p.L430= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs756681243, COSV56222251; called by mutect2, varscan2
- ITIH1 | c.2205C>T p.I735= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV56256758; called by mutect2, varscan2
- JAZF1 | c.411G>A p.V137= | Silent (SNP) | VAF 38/325 reads (12%) | catalogued as rs777973756, COSV52244619; called by muse, mutect2, varscan2
- KCNB2 | c.2289G>A p.Q763= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs866260081, COSV73049092, COSV73051127; called by muse, mutect2, varscan2
- KCNJ1 | c.528G>A p.G176= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV60662647; called by muse, mutect2
- KIF25 | c.912G>A p.G304= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs948026321, COSV63028687; called by muse, mutect2, varscan2
- LIM2 | c.396G>A p.G132= (on ENST00000596399 / NM_001161748.2; = p.G174= on NM_030657.4) | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV55742096; called by muse, mutect2, varscan2
- MED16 | c.1848G>A p.Q616= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV54131138; called by muse, mutect2, varscan2
- MOGAT3 | c.1023C>T p.I341= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV56176678; called by muse, mutect2, varscan2
- MYH7 | c.4428C>T p.S1476= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV62523044; called by muse, mutect2, varscan2
- NEXN | c.411G>A p.R137= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV53944379; called by muse, mutect2, varscan2
- NLRP12 | c.516C>T p.V172= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100145922; called by muse, mutect2, varscan2
- OR10H2 | c.687C>T p.I229= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV59946879; called by muse, mutect2, varscan2
- OR13C8 | c.207C>T p.L69= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as COSV58611362; called by muse, mutect2
- OR2A12 | c.540C>T p.I180= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV68821897; called by mutect2, varscan2
- OR2Z1 | c.429G>A p.L143= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV60693183; called by mutect2, varscan2
- OR8D1 | c.213C>T p.F71= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV63442925; called by muse, mutect2, varscan2
- PARP12 | c.330G>A p.K110= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV54936640; called by muse, mutect2
- PDZD4 | c.1899C>T p.T633= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV51250338; called by muse, mutect2, varscan2
- PGLYRP4 | c.699G>A p.A233= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs747128814, COSV62836181; called by mutect2, varscan2
- PKHD1L1 | c.4920G>T p.L1640= | Silent (SNP) | VAF 57/297 reads (19%) | catalogued as COSV65751059; called by muse, mutect2, varscan2
- POM121L12 | c.468G>A p.Q156= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs999710286, COSV68693431; called by muse, mutect2, varscan2
- PRUNE2 | c.9060C>T p.F3020= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs868136530, COSV56319526; called by mutect2, varscan2
- PTPRB | c.3633C>T p.P1211= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99718963; called by muse, mutect2, varscan2
- RAPGEF4 | c.2670G>A p.K890= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV51411145; called by muse, mutect2, varscan2
- RFX7 | c.3621C>T p.S1207= (on ENST00000559447 / NM_001368074.1; = p.S1304= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV57968063; called by muse, mutect2, varscan2
- SARS1 | c.855C>T p.L285= | Silent (SNP) | VAF 70/539 reads (13%) | catalogued as COSV52322819; called by muse, mutect2, varscan2
- SI | c.3570G>A p.G1190= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs868505324, COSV52297504; called by muse, mutect2, varscan2
- SLC12A3 | c.213C>T p.A71= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV52638461; called by muse, mutect2, varscan2
- SLC25A13 | c.1530C>T p.S510= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99674198; called by muse, mutect2, varscan2
- SLC36A2 | c.48C>T p.I16= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as COSV58864792; called by mutect2, varscan2
- SNX15 | c.279C>T p.I93= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs375033086; called by mutect2, varscan2
- TKTL1 | c.126G>A p.T42= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs374528241, COSV54213455; called by muse, mutect2, varscan2
- TRBV19 | c.141C>T p.N47= | Silent (SNP) | VAF 37/161 reads (23%) | called by muse, varscan2
- TTN | c.78513C>T p.A26171= (on ENST00000591111; = p.A18747= on NM_003319.4) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV60293988; called by muse, mutect2, varscan2
- UROS | c.450C>T p.I150= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV64226279; called by muse, varscan2
- WDFY3 | c.2085A>C p.A695= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV55712090; called by muse, mutect2, varscan2
- ZAN | c.4092A>G p.P1364= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV61814956; called by muse, mutect2
- ZNF211 | c.663C>T p.A221= (on ENST00000347302 / NM_198855.4; = p.A234= on NM_006385.5) | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV53742062; called by muse, mutect2
- ZNF266 | c.996C>T p.S332= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV63222983; called by muse, mutect2, varscan2
- ZSWIM5 | c.3504G>A p.Q1168= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as COSV55801780; called by muse, mutect2, varscan2
- ZSWIM5 | c.2466C>T p.L822= | Silent (SNP) | VAF 37/213 reads (17%) | catalogued as COSV62734050; called by muse, mutect2, varscan2
- COP1 | c.2133+18537C>T | Intron (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100443918; called by muse, mutect2
- IGLL5 | chr22:22899639 C>T | 3'Flank (SNP) | VAF 6/49 reads (12%) | called by mutect2, varscan2
- RTEL1 | c.3652+18G>A | Intron (SNP) | VAF 22/80 reads (28%) | catalogued as COSV53929003; called by muse, mutect2, varscan2
- TTN | c.10361-5379G>A | Intron (SNP) | VAF 13/49 reads (27%) | catalogued as COSV60170311; called by muse, mutect2, varscan2
